Gene-level copy-number profile of tumor specimen TCGA-D5-5539-01A from TCGA case TCGA-D5-5539, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.5 years (22,097 days).
Specimen TCGA-D5-5539-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.e0871617-a9dd-4155-9435-84a0157dac98.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D5-5539-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1494760b-8f39-49e9-8a82-371116867999

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,177; copy number 2: 4,638; copy number 3: 26,286; copy number 4: 21,783; copy number 5: 1,581; copy number 6: 670; copy number 7: 1,048; copy number 8: 2,592; copy number 12: 26; copy number 17: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D5-5539-01A-01D-1649-01): tumor purity 0.55, ploidy 3.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,573,767–6,705,558, 2 genes: AC007223.1, AC007012.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,675 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–211,316,385, 1,777 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr1:211,658,657–211,675,630, 1 gene, copy number 8 (within-gene range 2–8): NEK2.
- chr1:211,675,749–248,919,946, 814 genes, copy number 8 (broad region; genes not listed).
- chr7:14,814,131–15,696,886, 8 genes, copy number 7: AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1.
- chr8:126,474,189–128,564,679, 35 genes, copy number 12–17: AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr13:26,222,191–41,443,666, 256 genes, copy number 7 (broad region; genes not listed).
- chr13:41,566,835–41,961,120, 1 gene, copy number 7 (within-gene range 2–7): VWA8.
- chr13:41,807,677–81,302,407, 507 genes, copy number 7 (broad region; genes not listed).
- chr13:84,086,802–107,867,496, 276 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,177. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
